Surgical pathology report (de-identified scan), TCGA case TCGA-Y8-A897, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Spectrum Health, specimen TCGA-Y8-A897-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Carcinoma papillary renal
cell 8260/3
Site of Kidney NOS 8649
J11/22/13

Research Gross Description

female with renal lesion

Research Dx

Left renal mass, robotic left partial nephrectomy:
Papillary renal cell carcinoma, type 2, see summary.

CASE SUMMARY FOR NEPHRECTOMY FOR RENAL CELL CARCINOMA:

Procedure: robotic left partial nephrectomy and robotic hysterectomy with bilateral salpingo-oophorectomy, regional lymph node dissections.

Specimen laterality: left

Tumor site: upper pole

Tumor size: 1.8 cm

Extent of disease: tumor limited to kidney

Histologic type: papillary renal cell carcinoma, type 2.

Sarcomatoid features: not appreciated

Tumor necrosis: not appreciated

Histologic grade (Fuhrman Nuclear Grade): grade 2

Margins: free of tumor

Lymphovascular invasion: not appreciated.

Pathologic staging (pTNM):

Primary tumor: Tumor 4 cm or less in greatest dimension, limited to the kidney

Regional lymph nodes

Number examined: 34

Number involved: 0

Distant metastasis: unknown

Pathologic findings in nonneoplastic kidney: none

Other tumors and/or tumor-like lesions: none in kidney

AJCC Staging (7th edition) pT1a pN0 pM not applicable

Research QC

Tumor:

66% tumor nuclei

0% necrosis

35% normal stroma

Normal:

100% kidney

Research Specimen

-

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time

Buffy coat frozen time

Cold ischemia start time:

Formalin fixation start time:

[page 2 of 2]
Total cold ischemia time:
Formalin fixation stopped time:
Total formalin fixation time:

Specimen Weight

Normal-cortex
1-290 mg
Tumor
1-200 mg

Specimen Size

Plasma x 3
Serum x 2
Buffy coat x 1

Cryovials x 2
Normal x 1
Tumor x 1

FFPE x 2
Normal x 1
Tumor x 1

Study

Patient Consent

Yes

HPA2 Discrepancy		✓
Local/Synchronous Primary (Noted)		✓

Source: NCI Genomic Data Commons file c322c1f3-6898-4d43-a1e9-a10adf61b4af (TCGA-Y8-A897.9C29F0CD-C1FA-481F-86D7-C222A4F50966.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).